TARGET case TARGET-30-PASTGH — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/85c14369-f1ff-5054-b5e3-ed2d3c580260

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 18 years; Vital status: Dead; Days to death: 1,766 days (4.8 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 18.6 years (6,800 days); Year of diagnosis: 2009; Days to last follow up: 1,766 days (4.8 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Percent tumor nuclei: 50.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (6 entries)
- Days to follow up: 817 days (2.2 years); Progression or recurrence anatomic site: Vertebral column; Days to first event: 817 days (2.2 years); First event: Relapse.
- Days to follow up: 817 days (2.2 years); Progression or recurrence anatomic site: Lung, NOS.
- Days to follow up: 817 days (2.2 years); Progression or recurrence anatomic site: Bone, NOS.
- Days to follow up: 817 days (2.2 years); Progression or recurrence anatomic site: Liver.
- Days to follow up: 817 days (2.2 years); Progression or recurrence anatomic site: Lymph node, NOS.
- Days to follow up: 1,766 days (4.8 years); Year of follow up: 2014.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASTGH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-30-PASTGH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1766
- Protocol: ANBL00B1, ANBL0032
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.42
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Site of Relapse: Bone; Lymph Nodes; Other, specify: Liver; Lung (parenchymal); paravertebral tumours with extension in spinal canal (epidural cavity)
